Gene-level copy-number profile of tumor specimen ALCH-AENC-TTR1-A from ALCHEMIST case ALCH-AENC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,173 days).
Specimen ALCH-AENC-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7b442b51-24f3-4714-8180-ee01cd9b7dfe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AENC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/5d954fe0-4fda-49ad-813e-172727cd864c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 1,144; copy number 2: 16,108; copy number 3: 14,192; copy number 4: 20,772; copy number 5: 4,842; copy number 6: 324; copy number 7: 862; copy number 8: 12; copy number 9: 16; copy number 10: 1; copy number 11: 19; copy number 12: 2; copy number 13: 3; copy number 14: 2; copy number 17: 11; copy number 19: 35.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:20,999,596–22,706,703, 53 genes (within-gene range 0–2): USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 89 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,244,179–6,394,391, 4 genes, copy number 12–14: HES3, GPR153, ACOT7, AL031848.2.
- chr1:6,521,347–7,769,706, 15 genes, copy number 11 (within-gene range 5–12): NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, CAMTA1-DT, CAMTA1, AL590128.1, AL512330.1, RNU1-8P.
- chr1:7,693,124–8,344,167, 23 genes, copy number 9–17: AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr1:28,887,091–29,120,046, 4 genes, copy number 19 (within-gene range 7–19): EPB41, AL138785.1, Y_RNA, Metazoa_SRP.
- chr2:240,701,204–240,701,685, 1 gene, copy number 9: AC011298.2.
- chr5:165,220,577–165,241,756, 1 gene, copy number 10: LINC01938.
- chr6:105,096,822–106,975,627, 31 genes, copy number 19: BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, LINC02836, Z97206.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24.
- chr11:1,049,880–1,055,749, 1 gene, copy number 13: LINC02688.
- chr14:105,639,559–105,669,843, 4 genes, copy number 9 (within-gene range 5–9): IGHG2, MIR8071-2, COPDA1, IGHGP.
- chr16:1,064,093–1,078,731, 2 genes, copy number 9: SSTR5-AS1, AC009041.2.
- chr19:1,259,384–1,279,244, 3 genes, copy number 9–13: CIRBP, CIRBP-AS1, FAM174C.

Autosomal genes at a single copy (total copy number 1): 1,144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
